Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VO, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VO-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Report Status: Final

Procedure Date:

ICDO-3

Mesothelioma, epithelioid type
malignant 9052/3
Site: R Pleura NOS C38.4
Q613/14

PATHOLOGIC DIAGNOSIS:

A. PORT SITE 1:

Skin, subcutaneous soft tissue, and skeletal muscle with scar and foreign body giant cell reaction.
There is no evidence of malignancy.

B. RIB:

Bone marrow with maturing trilineage hematopoiesis.
There is no evidence of malignancy.

C. LEVEL 9:

One (1) lymph node, negative for tumor.

D. LEVEL 8:

One (1) lymph node, negative for tumor.

E. RIGHT LUNG, DIAPHRAGM, PERITONEUM, PERICARDIUM, (INCLUDING FSA):

DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE.

Tumor involves chest wall parietal pleura, maximal thickness of 4cm and mediastinal pleura and diaphragmatic pleura.

Tumor involves visceral pleura.

Visceral pleural involvement by tumor is confluent and includes an interlobar fissure.

Tumor invades lung parenchyma through the diaphragm to the peritoneum does NOT extend to the inner surface of the pericardium.

Tumor is present at all resection margins.

Lymphovascular invasion is not identified.

"Diaphragmatic" LYMPH NODES:

Metastatic mesothelioma present in 1 of 1 lymph node(s).

"Intraparenchymal" LYMPH NODES:

Metastatic mesothelioma present in 0 of 2 lymph node(s).

AJCC Classification (7th edition): ypT4N2M1 (including all parts).

NOTE:

The tumor is present at the bronchial resection margin on the frozen section slide, but not the permanent slide.

F. OMENTAL BIOPSY (INCLUDING FSB):

MALIGNANT MESOTHELIOMA, epithelioid type, involving fibroadipose tissue.

G. LEVEL 7:

Two (2) lymph nodes, negative for tumor.

H. 4R:

METASTATIC MALIGNANT MESOTHELIOMA, epithelioid type, involving two (2) lymph nodes.

I. OMENTUM:

MALIGNANT MESOTHELIOMA, epithelioid type, involving fibroadipose tissue.

J. CHEST WALL:

[page 2 of 4]
Pathology Report

MALIGNANT MESOTHELIOMA, epithelioid type, involving fibroadipose tissue and skeletal muscle.

K. PORT SITE 2:

Skin, subcutaneous soft tissue and skeletal muscle with scar, foreign body giant cell reaction and chronic inflammation.
There is no evidence of malignancy.

TISSUE SUBMITTED:

A/1. Port site #1.
B/2. Rib.
C/3. Level 9.
D/4. Level 8.
E/5. Right lung, diaphragm, peritoneum, pericardium.
F/6. Omental biopsy (FS).
G/7. Level 7.
H/8. 4R.
I/9. Omentum.
J/10. Chest wall.
K/11. Port site #2.

O.R. CONSULTATION:

SPECIMEN LABELED "5. RIGHT LUNG, DIAPHRAGM, PERITONEUM, PERICARDIUM" (FSA):
Epithelioid malignant mesothelioma present in small nests in bronchial resection margin soft tissue.

SPECIMEN LABELED "6. OMENTAL BX" (FSB):
Metastatic malignant mesothelioma.

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnosis(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in eleven parts, each labeled with the patient's name and medical record number.

Part A, "#1. Port site #1", consists of multiple soft tissue fragments (4.6 x 4.5 x 1.6 cm) consisting of skin (3.2 x 0.7 cm) with underlying soft tissue up to a depth of 4.4 cm. There are no masses or lesions identified.

Micro A1: Skin with underlying soft tissue, 3 frags.
Micro A2: Soft tissue fragments, 3 frags,

Part B, "#2. Rib", consists of two segments of rib (12.8 x 1.5 x 0.9 cm, 6.4 x 1.6 x 0.9 cm) with scant attached fragments of red/brown ragged skeletal muscle. A rib bone marrow squeeze is submitted for histologic examination.

Micro B1: Rib bone marrow squeeze, multi frags,

Part C, "#3. Level 9", consists of two tan/pink/brown soft tissue fragments (1.2 x 0.9 x 0.6 cm in aggregate). The specimen is entirely submitted for histologic examination.

Micro C1: Soft tissue fragments, 2 frags,

Part D, "#4. Level 8", consists of a tan/pink soft tissue fragment (1.5 x 1.5 x 0.8 cm). The specimen is entirely submitted for histologic examination.

[page 3 of 4]
Pathology Report

Micro D1: Soft tissue fragment, bisected, 2 frags,

Part E, "#5. Right lung, diaphragm, peritoneum, pericardium", consists of a 750-gram right extrapleural pneumonectomy specimen (23 x 17.3 x 4 cm) including lung (20 x 11.1 x 6.5 cm), open bronchial resection margin (2.3 cm in length x 1.8 cm in diameter), parietal pleura, pericardium (14 x 7.4 cm) and hemidiaphragm (31.8 x 19.5 x 11 cm). The parietal pleura contains greater than a hundred tan/white nodules (up to 4 cm in greatest dimension), is disrupted, and adherent only to the apex of the lung. All parietal pleural disruption margins are positive for tumor. The visceral pleura contains greater than two hundred tan/white surface nodules (up to 1.8 cm in greatest dimension) that are present on all lobes. The hemidiaphragm is disrupted and connected only to the anterior parietal pleura. Both surfaces of the hemidiaphragm are covered by greater than one hundred tan/white surface nodules (up to 10 cm in greatest dimension). All diaphragmatic margins are grossly positive for tumor. The bronchial margin is grossly free of tumor and entirely frozen en face for frozen section analysis as FSA. The pericardium contains three full thickness tan/white nodules (up to 2.4 cm in greatest dimension). The tumor extends into the lung parenchyma in the lower lobe and thickens the entire length of all of the intralobular septae. The uninvolved lung parenchyma shows mild emphysematous changes. Gross photographs are taken.

Micro E1: Bronchial resection margin, FSA remnant, 1 frag, ESS.
Micro E2: Apical parietal pleural margin, 1 frag, RSS.
Micro E3: Medial parietal pleural margin, 1 frag, RSS.
Micro E4: Lateral parietal pleural margin, 1 frag, RSS.
Micro E5: Anterior parietal pleural margin, 1 frag, RSS.
Micro E6: Posterior parietal pleural margin, 1 frag, RSS.
Micro E7: Medial diaphragm margin, 1 frag, RSS.
Micro E8: Lateral diaphragm margin, 1 frag, RSS.
Micro E9: Anterior diaphragm margin, 1 frag, RSS.
Micro E10: Posterior diaphragm margin, 1 frag, RSS.
Micro E11: Diaphragm and tumor, full thickness section, 1 frag, RSS.
Micro E12: Tumor and interlobar septae, 1 frag, RSS.
Micro E13: Tumor with extension into lung parenchyma, 2 frags, RSS.
Micro E14: Upper lobe, uninvolved parenchyma, 1 frag, RSS.
Micro E15: Middle lobe, uninvolved parenchyma, 1 frag, RSS.
Micro E16: Lower lobe, uninvolved parenchyma, 1 frag, RSS.
Micro E17: Pericardium with tumor, 2 frags, RSS.

Part F, "#6. Omental biopsy", consists of tan/yellow soft tissue and lobulated adipose tissue (13.5 x 12 x 0.3 cm) with few scattered firm tan/white nodules (up to 0.3 cm in greatest dimension) and focal hemorrhage. A representative section of soft tissue and nodules is submitted for frozen section analysis as FSB.

Micro F1: Soft tissue and nodule, FSB remnant, 1 frag, ESS.
Micro F2: Soft tissue and nodules, 2 frags, RSS.

Part G, "#7. Level 7", consists of two tan/brown soft tissue fragments (1.3 x 1.1 x 0.7 cm in aggregate). The specimen is entirely submitted for histologic examination.

Micro G1: Soft tissue fragments, 2 frags, ESS.

Part H, "#8. 4R", consists of a tan/yellow soft tissue fragment (2.5 x 1.4 x 0.8 cm) containing one potential lymph node. The specimen is entirely submitted for histologic examination.

Micro H1: Potential lymph node, 1 frag, ESS.

Part I, "#9. Omentum", consists of yellow lobulated fibroadipose tissue (15 x 12.2 x 4.5 cm) with no masses grossly identified. Representative sections are submitted for histologic examination.

Micro I1-I3: Fibroadipose tissue, 1 frag each, RSS.

[page 4 of 4]
Pathology Report

Part J, "#10. Chest wall", consists of a soft tissue fragment (5.1 x 2.8 x 1.4 cm) with a smooth glistening serosalized surface (6.3 x 2.8 cm) that is 80% covered by tan/white nodules (up to 1.4 cm in greatest dimension). The remainder of the specimen is tan/brown/pink soft tissue mixed with red/brown ragged skeletal muscle.

Micro J1-J3: Nodules with underlying soft tissue, 1 frag each, RSS.

Part K, "#11. Port site #2", consists of two soft tissue fragments (4.1 x 3.5 x 1.7 cm) containing skin (2.1 x 0.9 cm) and underlying soft tissue up to a depth of 3.5 cm. There are no masses or lesions identified.

Micro K1: Skin and underlying soft tissue, 1 frag, RSS.

Micro K2: Underlying soft tissue, 1 frag, RSS.

Micro K3: Additional soft tissue fragment, 1 frag, RSS.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file 85f3a5e8-7227-4fe3-9093-33c90deb7e25 (TCGA-ZN-A9VO.D10B7DE3-1AE6-42A3-BC9A-53CECC84BD96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).